Gene-level copy-number profile of tumor specimen TCGA-69-8255-01A from TCGA case TCGA-69-8255, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,289 days).
Specimen TCGA-69-8255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8c6c82bb-e677-430e-89c0-eb0e8faad85f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-8255-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74a80838-9695-441f-b10c-2e5e8c14b7c8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,104; copy number 2: 17,134; copy number 3: 19,311; copy number 4: 13,218; copy number 5: 4,930; copy number 6: 1,395; copy number 7: 1,164; copy number 8: 218; copy number 9: 187; copy number 10: 121; copy number 11: 3; copy number 15: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-8255-01A-11D-2283-01): tumor purity 0.37, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:83,650,249–84,563,236, 11 genes: AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1, MTND4P1, MTND5P3, LINC00333.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,452 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:39,249,266–39,437,301, 1 gene, copy number 8 (within-gene range 5–8): MAP4K3.
- chr2:39,436,530–39,779,267, 3 genes, copy number 8: MAP4K3-DT, TMEM178A, THUMPD2.
- chr2:39,929,110–39,929,998, 1 gene, copy number 8: AC007253.1.
- chr2:49,918,503–60,100,200, 107 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:116,687,218–116,818,761, 4 genes, copy number 9: AC104408.1, AC062016.1, MTCYBP39, AC062016.2.
- chr3:140,678,064–146,544,856, 86 genes, copy number 8 (broad region; genes not listed).
- chr3:149,517,235–149,736,714, 1 gene, copy number 9 (within-gene range 6–9): WWTR1.
- chr3:149,648,997–156,817,062, 134 genes, copy number 9–10 (broad region; genes not listed).
- chr4:38,758,791–43,234,956, 96 genes, copy number 7 (broad region; genes not listed).
- chr4:63,128,311–63,529,761, 3 genes, copy number 9: AC097491.1, LARP1BP1, AC093730.1.
- chr4:68,537,184–75,630,716, 151 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr4:76,214,040–76,783,253, 14 genes, copy number 7 (within-gene range 4–7): FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH.
- chr7:63,011,463–69,046,803, 210 genes, copy number 7 (broad region; genes not listed).
- chr8:37,405,439–37,844,896, 16 genes, copy number 15 (within-gene range 6–15): AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2.
- chr8:38,510,834–43,131,180, 97 genes, copy number 7–10 (broad region; genes not listed).
- chr8:54,509,422–55,542,054, 9 genes, copy number 9: RP1, SEC11B, AC090151.1, AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1.
- chr8:104,981,164–105,011,568, 3 genes, copy number 11: AC090142.2, AC090142.3, AC090142.1.
- chr8:140,505,813–145,066,685, 202 genes, copy number 7 (broad region; genes not listed).
- chr12:20,361,732–22,618,868, 37 genes, copy number 8 (within-gene range 5–8): AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2.
- chr17:59,841,266–68,797,822, 277 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
